Gene-level copy-number profile of tumor specimen ALCH-AEJ6-TTP1-A from ALCHEMIST case ALCH-AEJ6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 54.6 years (19,944 days).
Specimen ALCH-AEJ6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ea23640e-812c-493d-b4e6-fbe85e0b58e0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEJ6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/fb8c9cd9-977c-4f59-9feb-147d41044160

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 12,897; copy number 2: 39,997; copy number 3: 4,679; copy number 4: 560; copy number 5: 522; copy number 6: 136; copy number 7: 20; copy number 8: 23; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:840,999–856,247, 2 genes: PRTN3, ELANE.
- chr19:1,228,287–1,244,825, 3 genes (within-gene range 0–1): CBARP, AC004221.1, ATP5F1D.
- chr19:49,361,783–49,388,091, 2 genes (within-gene range 0–2): DKKL1, AC010643.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 705 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,785,583, 17 genes, copy number 7: SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273.
- chr3:178,164,008–179,147,973, 10 genes, copy number 5–7: AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2.
- chr5:8,754,869–30,365,684, 266 genes, copy number 5 (broad region; genes not listed).
- chr5:32,522,758–45,895,970, 206 genes, copy number 5 (broad region; genes not listed).
- chr8:36,378,069–43,674,591, 178 genes, copy number 5–8 (broad region; genes not listed).
- chr8:83,912,713–84,921,844, 5 genes, copy number 5 (within-gene range 2–5): AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P.
- chr14:89,110,148–89,111,223, 1 gene, copy number 5: MPPE1P1.
- chr16:32,213,380–32,213,503, 1 gene, copy number 5: AC133485.1.
- chr21:33,903,453–34,375,364, 12 genes, copy number 6 (within-gene range 2–6): ATP5PO, LINC00649, RN7SL740P, AP000569.1, MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1, AP000320.1, KCNE2.
- chr21:41,141,493–41,167,629, 2 genes, copy number 9: LINC00323, MIR3197.
- chr21:41,175,231–41,186,788, 2 genes, copy number 9 (within-gene range 2–9): PLAC4, BACE2-IT1.
- chr22:18,873,543–18,947,732, 5 genes, copy number 8 (within-gene range 3–8): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 10,112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
